Gene-level copy-number profile of specimen HCM-CSHL-0598-C25-85B from HCMI case HCM-CSHL-0598-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 57.1 years (20,872 days).
Specimen HCM-CSHL-0598-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a5c5a0fb-e969-4c52-95e8-ddc7705d0ee1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0598-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/c030572a-1276-4067-a776-4e7050e0307e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,776; copy number 2: 14,920; copy number 3: 33,222; copy number 4: 5,541; copy number 5: 239; copy number 6: 30; copy number 7: 109; copy number 9: 68.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 177 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,314,591–39,838,289, 5 genes, copy number 7: ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2.
- chr22:18,110,331–21,325,042, 172 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
